CCDI case PBBUZK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/a7c76ce7-d948-4575-810b-05e21c0c48e2

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 5.1 years (1,871 days).

Biospecimens (3 samples)
- Sample 0DHY2X: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHY41: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHY4W: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
